Somatic mutation profile of tumor specimen ALCH-B3FD-TTP1-A (aliquot ALCH-B3FD-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3FD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.1 years (27,047 days).
Specimen ALCH-B3FD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af269474-2795-4d61-8543-8e231fd97ac5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3FD-NB1-A (Blood Derived Normal), aliquot ALCH-B3FD-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09631e30-9739-428b-b629-f4406f9b4602

The open-access MAF lists 123 somatic variants for this specimen: 76 protein-altering or splice-affecting, 32 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 32, Intron 7, 5'UTR 3, Nonsense Mutation 2, Frame Shift Del 2, 3'UTR 2, RNA 2, Frame Shift Ins 2, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 288/1262 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ADCY1 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 74/663 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99812137; called by muse, mutect2, varscan2
- ADCY2 | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 72/720 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.354); catalogued as rs1390769718, COSV57863600; called by muse, mutect2
- BMP7 | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 143/942 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs202153108; called by muse, mutect2, varscan2
- CCDC168 | c.8599G>A p.E2867K | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV70556020; called by muse, mutect2, varscan2
- CCDC168 | c.7185G>A p.M2395I | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as rs1420342317; called by muse, mutect2, varscan2
- CD79B | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 69/354 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs144755516; ClinVar: not provided; called by muse, mutect2, varscan2
- CERS3 | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 74/589 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs138661052, COSV52568776; called by muse, mutect2, varscan2
- CFAP46 | c.5720C>T p.A1907V | Missense Mutation (SNP) | VAF 115/716 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.494); catalogued as rs768754603, COSV54153984; called by muse, mutect2, varscan2
- CLDN4 | c.308A>C p.K103T | Missense Mutation (SNP) | VAF 38/290 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV52895899; called by muse, mutect2, varscan2
- CTNND2 | c.2281G>A p.V761I | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs370692250; called by muse, varscan2
- DOP1B | c.6827A>G p.D2276G | Missense Mutation (SNP) | VAF 88/976 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs758339078; called by muse, mutect2
- F7 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 54/346 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs767539514, CM004648, COSV60647217; called by muse, mutect2, varscan2
- HIPK4 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 89/458 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs201121603, COSV52521230; called by muse, mutect2, varscan2
- HIRIP3 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 42/273 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs199805442; called by muse, mutect2, varscan2
- INKA1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 130/684 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752136968; called by muse, mutect2, varscan2
- IRAG1 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs1311215199; called by muse, mutect2
- KCNN1 | c.629C>T p.T210M | Missense Mutation (SNP) | VAF 153/511 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs1195461639; called by muse, mutect2, varscan2
- MYH2 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 53/532 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs747990808, COSV55432843; called by muse, mutect2, varscan2
- NCSTN | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 171/934 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as rs200596888, COSV54187669; called by muse, mutect2, varscan2
- OR13C9 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 35/334 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as rs1449453306, COSV52241779, COSV52243398; called by muse, mutect2, varscan2
- PLEC | c.13309C>T p.R4437W (on ENST00000322810 / NM_201380.4; = p.R4327W on NM_000445.5) | Missense Mutation (SNP) | VAF 60/598 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs782022985, COSV59603750; called by muse, mutect2
- PLXNA4 | c.4291G>T p.E1431* | Nonsense Mutation (SNP) | VAF 23/189 reads (12%) | catalogued as COSV100326670; called by muse, mutect2, varscan2
- PRR23C | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 80/485 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV101356434, COSV68826891; called by muse, mutect2, varscan2
- PRUNE2 | c.6272C>T p.T2091M | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs184351514; called by muse, mutect2, varscan2
- PTCHD1 | c.2173G>A p.V725I | Missense Mutation (SNP) | VAF 28/345 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.104); catalogued as rs753840664; called by muse, mutect2
- SLC7A3 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 84/789 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.272); catalogued as rs1459882610; called by muse, mutect2, varscan2
- SRPX | c.938C>T p.T313M | Missense Mutation (SNP) | VAF 50/297 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs750284952, COSV100656054; called by muse, mutect2, varscan2
- SYNE2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 46/505 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764128650; ClinVar: uncertain significance; called by muse, mutect2
- TIMM44 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 122/864 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as rs1331569541; called by muse, mutect2, varscan2
- TNR | c.1183G>A p.V395I | Missense Mutation (SNP) | VAF 92/553 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.135); catalogued as rs1316869424, COSV54891795; called by muse, mutect2, varscan2
- TP53 | c.607G>T p.V203L | Missense Mutation (SNP) | VAF 100/629 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs730882003, COSV52761693, COSV52809012, COSV52965683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53BP1 | c.5437C>T p.R1813W | Missense Mutation (SNP) | VAF 49/449 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769912966, COSV53017916; called by muse, mutect2, varscan2
- TRIM66 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 63/603 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs896314219; called by muse, mutect2, varscan2
- TTC13 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 34/444 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as rs761168798, COSV64167879; called by muse, mutect2
- UNC5D | c.2431C>A p.L811I | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV54778195; called by muse, mutect2
- ZNF451 | c.880A>G p.I294V | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs147004118; called by muse, varscan2
- ZNF678 | c.1421C>G p.S474* | Nonsense Mutation (SNP) | VAF 52/680 reads (8%) | catalogued as rs891649374; called by muse, mutect2
- ZNF705G | c.839G>C p.G280A | Missense Mutation (SNP) | VAF 56/681 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs748358018; called by muse, mutect2
- ADNP2 | c.2226G>T p.M742I | Missense Mutation (SNP) | VAF 57/348 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ADNP2 | c.3139G>A p.E1047K | Missense Mutation (SNP) | VAF 35/323 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ANHX | c.881C>A p.T294K | Missense Mutation (SNP) | VAF 64/556 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- ATRX | c.4618G>T p.D1540Y | Missense Mutation (SNP) | VAF 60/576 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC168 | c.10359G>C p.K3453N | Missense Mutation (SNP) | VAF 47/398 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- CCDC168 | c.8284G>C p.E2762Q | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- CCDC168 | c.7789G>A p.E2597K | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CEACAM8 | c.521C>T p.T174I | Missense Mutation (SNP) | VAF 28/1018 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.302); called by muse, mutect2
- CNTNAP3 | c.1795G>C p.G599R | Missense Mutation (SNP) | VAF 33/249 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CPT1A | c.313G>T p.V105F | Missense Mutation (SNP) | VAF 71/573 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- CSMD1 | c.10042_10042+4delinsA p.X3348_splice (on ENST00000520002; = p.X3347_splice on NM_033225.6) | Splice Site (DEL) | VAF 16/107 reads (15%) | called by pindel, varscan2*
- DENND5A | c.1265dup p.E423* | Frame Shift Ins (INS) | VAF 111/870 reads (13%) | called by mutect2, pindel, varscan2
- FGD4 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 43/350 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GBA2 | c.259C>G p.R87G | Missense Mutation (SNP) | VAF 86/482 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- IL5RA | c.323T>C p.L108P | Missense Mutation (SNP) | VAF 75/493 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LIPI | c.142C>A p.L48I | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- MAPK7 | c.2122C>G p.P708A | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.257); called by muse, mutect2
- MAST3 | c.1141G>A p.V381I | Missense Mutation (SNP) | VAF 34/367 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- NAB1 | c.455T>A p.L152Q | Missense Mutation (SNP) | VAF 70/397 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- NPY2R | c.118C>A p.L40I | Missense Mutation (SNP) | VAF 46/386 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- OTOGL | c.4928G>A p.G1643D (on ENST00000547103; = p.G1634D on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/364 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PASD1 | c.1618A>G p.K540E | Missense Mutation (SNP) | VAF 75/479 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PPCS | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 51/560 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- RALGAPA2 | c.3462T>G p.N1154K | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RNF169 | c.1754G>C p.G585A | Missense Mutation (SNP) | VAF 67/607 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- SAMD10 | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 46/475 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2
- SCARF1 | c.1999_2000insA p.G667Efs*6 | Frame Shift Ins (INS) | VAF 18/126 reads (14%) | called by mutect2, pindel*, varscan2
- SCEL | c.2046del p.M683Wfs*15 (on ENST00000349847 / NM_144777.3; = p.M663Wfs*15 on NM_003843.4) | Frame Shift Del (DEL) | VAF 22/140 reads (16%) | called by mutect2, pindel, varscan2
- SCN2A | c.4206del p.V1403* | Frame Shift Del (DEL) | VAF 56/322 reads (17%) | called by mutect2, pindel, varscan2
- TMED8 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 37/358 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIM43 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 52/331 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- UCHL5 | c.489T>G p.F163L | Missense Mutation (SNP) | VAF 24/366 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- USP29 | c.1059T>A p.N353K | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- USP5 | c.1873G>A p.D625N | Missense Mutation (SNP) | VAF 151/851 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDFY4 | c.1835C>T p.S612L | Missense Mutation (SNP) | VAF 142/856 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- YBX2 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 126/827 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF831 | c.2672C>T p.S891F | Missense Mutation (SNP) | VAF 51/353 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AHCYL1 | c.1101C>T p.V367= | Silent (SNP) | VAF 49/425 reads (12%) | catalogued as rs752659106; called by muse, mutect2, varscan2
- ANPEP | c.120C>T p.N40= | Silent (SNP) | VAF 45/329 reads (14%) | catalogued as rs568774558, COSV100263330, COSV100263454; called by muse, mutect2, varscan2
- AXDND1 | c.978C>T p.F326= | Silent (SNP) | VAF 22/230 reads (10%) | catalogued as COSV62644797; called by muse, mutect2
- CSMD3 | c.1953T>C p.G651= (on ENST00000297405 / NM_001363185.1; = p.G547= on NM_052900.3) | Silent (SNP) | VAF 390/886 reads (44%) | called by muse, mutect2, varscan2
- EP400 | c.9255C>T p.G3085= | Silent (SNP) | VAF 88/529 reads (17%) | catalogued as rs956284454, COSV57776887; called by muse, mutect2, varscan2
- FLG2 | c.5856A>T p.G1952= | Silent (SNP) | VAF 211/842 reads (25%) | called by muse, mutect2, varscan2
- GJA3 | c.393G>A p.S131= | Silent (SNP) | VAF 36/287 reads (13%) | catalogued as rs749070481, COSV99576245; called by muse, mutect2, varscan2
- HCRT | c.75G>T p.A25= | Silent (SNP) | VAF 30/177 reads (17%) | called by muse, varscan2
- HLA-DQA2 | c.543T>C p.P181= | Silent (SNP) | VAF 156/1946 reads (8%) | called by muse, mutect2
- IQSEC3 | c.681G>A p.A227= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as rs781869274; called by muse, mutect2
- KDM4D | c.1125A>G p.R375= | Silent (SNP) | VAF 93/573 reads (16%) | called by muse, mutect2, varscan2
- KLHL14 | c.288G>A p.Q96= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- KRT16 | c.108C>T p.A36= | Silent (SNP) | VAF 48/230 reads (21%) | catalogued as rs774260784; called by muse, mutect2, varscan2
- L1CAM | c.2943C>T p.T981= | Silent (SNP) | VAF 57/319 reads (18%) | catalogued as rs782396488; called by muse, mutect2, varscan2
- MUC12 | c.3909C>A p.V1303= (on ENST00000379442; = p.V1160= on NM_001164462.1) | Silent (SNP) | VAF 271/1189 reads (23%) | called by muse, mutect2, varscan2
- NEU2 | c.276C>T p.D92= | Silent (SNP) | VAF 63/261 reads (24%) | catalogued as rs770635668, COSV52094053; called by muse, mutect2, varscan2
- OR5M11 | c.702C>T p.H234= | Silent (SNP) | VAF 30/196 reads (15%) | called by muse, mutect2, varscan2
- OR9G4 | c.21C>A p.T7= | Silent (SNP) | VAF 52/339 reads (15%) | catalogued as COSV57248413; called by muse, mutect2, varscan2
- PARP10 | c.2055C>T p.L685= | Silent (SNP) | VAF 24/443 reads (5%) | catalogued as rs1554748296, COSV100477919; called by muse, mutect2
- PARP14 | c.1677C>T p.F559= | Silent (SNP) | VAF 24/194 reads (12%) | called by muse, mutect2, varscan2
- POLR1A | c.843G>A p.S281= | Silent (SNP) | VAF 41/389 reads (11%) | catalogued as rs1419807566, COSV55695179; called by muse, mutect2, varscan2
- POTEA | c.114C>T p.S38= | Silent (SNP) | VAF 87/578 reads (15%) | called by muse, mutect2, varscan2
- PPCS | c.78C>T p.F26= | Silent (SNP) | VAF 23/178 reads (13%) | catalogued as rs1163785310, COSV65333686; called by muse, mutect2, varscan2
- RPUSD1 | c.627C>T p.H209= | Silent (SNP) | VAF 84/637 reads (13%) | catalogued as rs192944879, COSV50101912; called by muse, mutect2, varscan2
- SEMA3D | c.924G>A p.L308= | Silent (SNP) | VAF 68/666 reads (10%) | catalogued as rs545667383; called by muse, mutect2, varscan2
- SLC17A9 | c.513G>A p.G171= | Silent (SNP) | VAF 36/360 reads (10%) | called by muse, mutect2
- SPATA25 | c.546A>G p.Q182= | Silent (SNP) | VAF 22/408 reads (5%) | called by muse, mutect2
- YIPF4 | c.534C>G p.L178= | Silent (SNP) | VAF 54/319 reads (17%) | catalogued as COSV53212987; called by muse, varscan2
- ZFHX3 | c.9885G>A p.L3295= | Silent (SNP) | VAF 125/746 reads (17%) | called by muse, mutect2, varscan2
- ZNF185 | c.78C>A p.L26= | Silent (SNP) | VAF 20/371 reads (5%) | called by muse, mutect2
- ZNF585B | c.813C>T p.I271= | Silent (SNP) | VAF 65/514 reads (13%) | called by muse, varscan2
- ZSWIM4 | c.2559C>T p.L853= | Silent (SNP) | VAF 43/248 reads (17%) | catalogued as rs1399766012, COSV54323251; called by muse, mutect2, varscan2
- B4GALT7 | c.*46C>A | 3'UTR (SNP) | VAF 39/243 reads (16%) | called by muse, mutect2, varscan2
- CALCA | chr11:14967717 C>T | 3'Flank (SNP) | VAF 28/755 reads (4%) | catalogued as rs782595137, COSV59028186; called by muse, mutect2
- CIAO3 | c.693+39G>A | Intron (SNP) | VAF 62/457 reads (14%) | catalogued as rs746000897; called by muse, mutect2, varscan2
- DCUN1D4 | c.616-2095A>G | Intron (SNP) | VAF 78/641 reads (12%) | called by muse, mutect2, varscan2
- DTX3 | c.968+91C>T | Intron (SNP) | VAF 41/353 reads (12%) | catalogued as rs1364100717; called by muse, mutect2, varscan2
- GPI | c.123-359C>A | Intron (SNP) | VAF 62/1212 reads (5%) | called by muse, mutect2
- HHAT | c.-86G>A | 5'UTR (SNP) | VAF 12/89 reads (13%) | called by muse, mutect2, varscan2
- HSBP1L1 | c.-60T>C | 5'UTR (SNP) | VAF 11/71 reads (15%) | called by muse, mutect2, varscan2
- HSBP1L1 | c.-59C>T | 5'UTR (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- LINC00243 | n.302G>T | RNA (SNP) | VAF 53/470 reads (11%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-10660A>G | Intron (SNP) | VAF 81/542 reads (15%) | called by muse, mutect2, varscan2
- SGSM2 | c.*767dup | 3'UTR (INS) | VAF 47/365 reads (13%) | called by pindel, varscan2
- SYNE2 | c.19474-49G>C | Intron (SNP) | VAF 70/530 reads (13%) | called by muse, mutect2, varscan2
- TEX21P | n.1608G>A | RNA (SNP) | VAF 70/634 reads (11%) | catalogued as rs927092546; called by mutect2, varscan2
- TMEM51 | c.-267+17267G>A | Intron (SNP) | VAF 68/815 reads (8%) | catalogued as rs564648684; called by muse, mutect2
